Gene-level copy-number profile of tumor specimen HCM-CSHL-0192-C25-01A from HCMI case HCM-CSHL-0192-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 67.7 years (24,739 days).
Specimen HCM-CSHL-0192-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2a06dee2-a7d9-47e7-9206-5f7d66600f70.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0192-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/56f2370e-3463-4ff5-a3f1-7a3d38fec0de

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 530; copy number 1: 14,883; copy number 2: 40,857; copy number 3: 2,424; copy number 4: 67; copy number 5: 80; copy number 6: 70.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–1): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr8:12,178,697–12,194,133, 2 genes: ALG1L11P, FAM86B1.
- chr9:5,334,930–5,352,410, 2 genes: RLN1, AL135786.2.
- chr17:18,426,861–18,506,313, 8 genes: KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 150 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:35,005,990–35,990,270, 70 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr17:46,762,506–48,380,370, 63 genes, copy number 5 (within-gene range 5–6) (broad region; genes not listed).
- chr17:50,866,679–51,521,401, 17 genes, copy number 5 (within-gene range 1–5): TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073.

Autosomal genes at a single copy (total copy number 1): 12,537. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
